Somatic mutation profile of tumor specimen MBCProject_0471_T1A_WES (aliquot MBCProject_0471_T1A_WES_1) from CMI case MBCProject_0471, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 53.7 years (19,611 days).
Specimen MBCProject_0471_T1A_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08984b19-8aef-47be-baf5-0978fde19c21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0471_SALIVA (Saliva), aliquot MBCProject_0471_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ee0aa89-866c-4291-ad5b-e3bd50f786e5

The open-access MAF lists 27 somatic variants for this specimen: 16 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 8, Intron 2, In Frame Del 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP10A | c.2233G>A p.V745I | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs372138642; called by muse, mutect2, varscan2
- CASP1 | c.1075G>A p.E359K (on ENST00000436863 / NM_033292.4; = p.E338K on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99507959; called by muse, mutect2
- HERC2 | c.2908G>C p.E970Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV55314251; called by muse, mutect2, varscan2
- HIPK3 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224824771, COSV57561809; called by muse, mutect2, varscan2
- LINGO2 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58059759; called by muse, varscan2
- LINGO2 | c.470C>G p.S157C | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.873); catalogued as COSV58057226; called by muse, mutect2
- NLRP3 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 21/244 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs372038150; ClinVar: uncertain significance; called by muse, mutect2
- OR4C46 | c.576G>T p.M192I | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60221402; called by muse, mutect2, varscan2
- CC2D2A | c.4181G>C p.G1394A | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERN1 | c.1470G>C p.Q490H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAFAH1B1 | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- RP1 | c.1564_1566del p.H522del | In Frame Del (DEL) | VAF 14/122 reads (11%) | called by mutect2, pindel
- SLC12A1 | c.1393T>A p.Y465N | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SLC39A4 | c.144A>T p.L48F | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.994); called by muse, mutect2
- TJP1 | c.5203C>T p.L1735F | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.643); called by muse, mutect2
- XBP1 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- CHRNA4 | c.324C>T p.V108= | Silent (SNP) | VAF 13/62 reads (21%) | called by muse, mutect2, varscan2
- ERAS | c.492C>T p.A164= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs781800923, COSV99504908; called by muse, varscan2
- GHSR | c.1020C>T p.F340= | Silent (SNP) | VAF 11/138 reads (8%) | catalogued as rs144720427; ClinVar: likely benign; called by muse, mutect2
- KCNQ2 | c.384C>T p.I128= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs1568944832; called by muse, varscan2
- MVD | c.855C>T p.I285= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs1305178474; called by muse, mutect2, varscan2
- NEFL | c.897C>T p.R299= | Silent (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- NRSN2 | c.327C>T p.N109= | Silent (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- SEC16A | c.3519C>T p.Y1173= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- KCTD1 | c.-15-46455G>A | Intron (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1124-37T>A | Intron (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- ZNF711 | c.*4G>C | 3'UTR (SNP) | VAF 13/202 reads (6%) | called by muse, mutect2
